Gene-level copy-number profile of tumor specimen TCGA-29-1703-01A from TCGA case TCGA-29-1703, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G2; Age at diagnosis: 56.5 years (20,622 days).
Specimen TCGA-29-1703-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.0cf0722f-55bc-438b-92fd-d7f65d6b4ef4.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-29-1703-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 818 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/674c1e11-bb2a-49a9-a957-9efd6dbc6455

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 3,757; copy number 2: 23,544; copy number 3: 25,300; copy number 4: 3,143; copy number 5: 2,572; copy number 6: 410; copy number 7: 14; copy number 8: 309; copy number 9: 262; copy number 10: 59; copy number 11: 129; copy number 12: 145; copy number 13: 23; copy number 14: 35; copy number 15: 96; copy number 18: 7.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-29-1703-01A-01D-0559-01): tumor purity 0.93, ploidy 2.85, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,079 genes in 23 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:239,703,381–239,770,130, 1 gene, copy number 7: CHRM3-AS2.
- chr8:51,319,577–51,809,445, 1 gene, copy number 8 (within-gene range 6–12): PXDNL.
- chr8:51,721,670–56,776,874, 89 genes, copy number 9–12 (broad region; genes not listed).
- chr8:58,805,412–59,119,147, 1 gene, copy number 10 (within-gene range 4–10): TOX.
- chr8:58,991,720–66,667,231, 107 genes, copy number 8–18 (broad region; genes not listed).
- chr8:66,667,615–66,685,564, 1 gene, copy number 11: C8orf44.
- chr8:123,226,189–144,291,438, 360 genes, copy number 8–9 (within-gene range 2–9) (broad region; genes not listed).
- chr12:10,824,960–11,171,608, 1 gene, copy number 9 (within-gene range 2–9): PRH1.
- chr12:10,845,849–11,171,600, 1 gene, copy number 9 (within-gene range 2–9): AC018630.4.
- chr12:10,937,408–11,171,573, 1 gene, copy number 9 (within-gene range 2–9): TAS2R14.
- chr12:11,021,619–11,895,377, 28 genes, copy number 9: TAS2R19, TAS2R31, TAS2R63P, TAS2R46, TAS2R64P, TAS2R43, AC018630.1, TAS2R30, AC134349.2, AC134349.1, SMIM10L1, TAS2R42, AC244131.1, AC244131.2, PRB3, PRB4, PRB1, PRB2, AC078950.1, HIGD1AP8, AC007450.4, AC007450.3, DDX55P1, AC007450.2, AC007450.1, RNU7-60P, LINC01252, ETV6.
- chr12:12,111,163–12,112,036, 2 genes, copy number 9: PTMAP9, MIR1244-4.
- chr12:12,813,316–12,876,107, 4 genes, copy number 10: DDX47, AC007215.1, AC007688.2, RPL13AP20.
- chr12:25,959,029–26,421,462, 11 genes, copy number 7 (within-gene range 2–7): RASSF8, BHLHE41, SSPN, AC022509.3, AC022509.5, AC022509.2, AC022509.1, AC022509.4, AC055720.1, AC055720.3, AC024145.1.
- chr12:26,335,864–26,373,733, 2 genes, copy number 7: AC055720.2, RNA5SP354.
- chr12:30,795,458–39,619,803, 118 genes, copy number 8 (within-gene range 3–8) (broad region; genes not listed).
- chr12:44,508,275–46,972,155, 35 genes, copy number 14 (within-gene range 4–14): NELL2, Y_RNA, DBX2, AC008127.1, RACGAP1P1, SSBL3P, RNA5SP361, AC009248.3, PLEKHA8P1, AC009248.1, ANO6, AC009248.2, AC063924.1, AC079950.1, U6, AC008124.1, ARID2, AC009464.1, RN7SL246P, KNOP1P2, SCAF11, AC084878.1, SLC38A1, AC025031.3, SLC38A2, AC025031.2, AC008014.1, AC025031.1, AC025031.4, AC025031.5, AC008035.1, OR7A19P, MARK3P1, SLC38A4, AC079906.1.
- chr17:26,981,694–28,617,377, 87 genes, copy number 12 (broad region; genes not listed).
- chr18:5,392,381–5,630,700, 1 gene, copy number 10 (within-gene range 6–10): EPB41L3.
- chr18:5,567,130–6,937,020, 27 genes, copy number 8–10: AP005059.1, MIR3976HG, MIR3976, TMEM200C, AP001021.1, AP001021.3, L3MBTL4, AP001021.2, RNU5F-3P, L3MBTL4-AS1, MIR4317, AP005060.1, RNU6-349P, RPL6P27, AP005202.2, LINC01387, AP005202.1, RN7SL282P, AP005205.1, AP005205.3, AP005205.2, ARHGAP28, AP005210.2, AP005210.1, LINC00668, SCML2P1, RNU6-916P.
- chr18:6,954,677–6,957,419, 1 gene, copy number 8: AP002409.1.
- chr19:27,793,431–27,984,984, 1 gene, copy number 11 (within-gene range 6–11): AC006504.5.
- chr19:27,849,635–35,372,962, 199 genes, copy number 11–15 (within-gene range 6–15) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 2,338. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
